Somatic mutation profile of tumor specimen TCGA-KK-A6E6-01A (aliquot TCGA-KK-A6E6-01A-11D-A30X-08) from TCGA case TCGA-KK-A6E6, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.3 years (25,320 days).
Specimen TCGA-KK-A6E6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32045524-a32e-4c77-9ed2-e44fd6f492ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E6-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E6-11A-11D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/831f1e0a-cda0-4e69-8440-f442bf75e5f0

The open-access MAF lists 36 somatic variants for this specimen: 21 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 13, Frame Shift Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL5 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955009057, COSV59936213; called by muse, mutect2, varscan2
- C10orf53 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV65108101; called by muse, mutect2, varscan2
- CDH26 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs369677402, COSV54850586; called by muse, mutect2
- GUCY2F | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs748353714, COSV54298617; called by muse, mutect2, varscan2
- HECW1 | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771124413, COSV67835802; called by muse, mutect2, varscan2
- KLHDC4 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV54511135; called by muse, mutect2, varscan2
- LAMB3 | c.890A>C p.Y297S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV61919464; called by muse, mutect2
- NPC1 | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV52580291; called by mutect2, varscan2
- OR10R2 | c.742A>C p.I248L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV63769463; called by muse, mutect2
- PCNX4 | c.2315G>T p.C772F (on ENST00000406854 / NM_001330177.2; = p.C538F on NM_022495.5) | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV58307674; called by muse, mutect2, varscan2
- PNMT | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs768713506, COSV54093938; called by muse, mutect2, varscan2
- PTPRC | c.2200G>C p.D734H | Missense Mutation (SNP) | VAF 17/519 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61420004; called by muse, mutect2
- SALL1 | c.1023G>T p.M341I | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51754529, COSV51764126; called by muse, mutect2
- SH3BGRL2 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs371878206; called by muse, mutect2, varscan2
- SLC9C2 | c.485T>C p.I162T | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62949009; called by muse, mutect2
- TEX11 | c.1751G>A p.R584H (on ENST00000344304; = p.R569H on NM_031276.3) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs1350493086, COSV60232564; called by muse, mutect2, varscan2
- TFAP2B | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV53831023; called by muse, mutect2, varscan2
- TMEM209 | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV61023571; called by mutect2, varscan2
- XPO5 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54834601; called by muse, mutect2, varscan2
- ZNF707 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs370307757; called by muse, mutect2
- TMEM237 | c.550dup p.S184Kfs*8 (on ENST00000409883 / NM_001044385.3; = p.S176Kfs*8 on NM_152388.4) | Frame Shift Ins (INS) | VAF 18/122 reads (15%) | called by mutect2, pindel, varscan2
- COG7 | c.1599T>C p.N533= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV56152936; called by muse, mutect2, varscan2
- FAM151A | c.813G>A p.T271= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs569041271, COSV56366184; called by muse, mutect2, varscan2
- KIF16B | c.2193C>T p.D731= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV61713941; called by muse, mutect2, varscan2
- LPAR4 | c.480T>C p.A160= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV70913344; called by muse, mutect2, varscan2
- NEURL4 | c.3540C>T p.F1180= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV59753115; called by muse, mutect2, varscan2
- PXDNL | c.2601C>T p.P867= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV62482797, COSV62486935; called by muse, mutect2, varscan2
- SUPT5H | c.2424G>A p.L808= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV63241902; called by muse, mutect2, varscan2
- TAS2R14 | c.177T>G p.V59= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV67863000; called by mutect2, varscan2
- TBC1D19 | c.222T>C p.F74= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV53521199; called by muse, mutect2, varscan2
- TIE1 | c.2373G>T p.L791= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV65251237; called by mutect2, varscan2
- TXNDC2 | c.1623T>G p.L541= (on ENST00000306084 / NM_001098529.2; = p.L474= on NM_032243.6) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV60155515; called by muse, mutect2
- WNT1 | c.399C>T p.A133= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV53296846; called by muse, mutect2, varscan2
- ZNF518B | c.183A>T p.A61= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as COSV58724659; called by muse, mutect2, varscan2
- CEP295 | chr11:93733579 C>G | 3'Flank (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- SERPINA13P | n.1036C>G | RNA (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
